Somatic mutation profile of tumor specimen C3L-00510-02 (aliquot CPT0011910007) from CPTAC case C3L-00510, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 80.3 years (29,337 days).
Specimen C3L-00510-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26fa22fb-164b-4d18-b02e-5fc743f9fa4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00510-31 (Blood Derived Normal), aliquot CPT0012490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ddce15b-f092-44fc-ad68-3ce08ec61e3b

The open-access MAF lists 59 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Intron 5, 3'UTR 2, In Frame Del 2, RNA 1, 5'UTR 1, Frame Shift Del 1, Nonstop Mutation 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 128/352 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 160/377 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AQR | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371432757; called by muse, varscan2
- ARF5 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.399); catalogued as rs774035808, COSV99133968; called by muse, mutect2, varscan2
- ATP13A3 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs746788728; called by muse, mutect2, varscan2
- CHRM3 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs201087854, COSV99698869; called by muse, mutect2, varscan2
- DRC7 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV61054373; called by muse, mutect2
- DUSP6 | c.1145G>T p.*382Lext*36 | Nonstop Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV54378040; called by muse, mutect2, varscan2
- EPB41 | c.691A>G p.K231E (on ENST00000343067 / NM_001166005.2; = p.K22E on NM_004437.4) | Missense Mutation (SNP) | VAF 129/342 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1253600912; called by muse, mutect2, varscan2
- MDGA2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264444599; called by muse, mutect2, varscan2
- OR52E2 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV58613391, COSV58613492; called by muse, mutect2, varscan2
- PRR23C | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as rs770562080, COSV68827501; called by muse, mutect2, varscan2
- SVEP1 | c.3301G>T p.V1101L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV57041497; called by muse, mutect2, varscan2
- TEX51 | c.269G>A p.R90Q (on ENST00000643416; = p.R72Q on NM_001322244.2) | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1478704254; called by muse, mutect2, varscan2
- TLE3 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1350882604, COSV58176062; called by muse, mutect2
- TRAPPC8 | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as rs961107701; called by muse, mutect2
- ULK3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1349452738; called by muse, mutect2
- ABCC6 | c.3106T>A p.F1036I | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACADVL | c.623-6C>A | Splice Region (SNP) | VAF 86/143 reads (60%) | called by muse, mutect2, varscan2
- ACADVL | c.1454C>G p.S485C | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2
- ACVR1B | c.270_277del p.R91Pfs*6 | Frame Shift Del (DEL) | VAF 60/196 reads (31%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.7754T>G p.I2585S | Missense Mutation (SNP) | VAF 116/358 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2
- CCDC17 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CFAP53 | c.1386A>T p.Q462H | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- DENND1B | c.1251G>T p.R417S | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FRMPD3 | c.3587C>A p.P1196H | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- GALNT9 | c.1319_1321del p.L440_K441delinsQ (on ENST00000328957 / NM_001122636.2; = p.L74_K75delinsQ on NM_021808.3) | In Frame Del (DEL) | VAF 38/160 reads (24%) | called by mutect2, pindel, varscan2
- GAPDH | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 171/246 reads (70%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- GAPDH | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- GAPDH | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- HEATR9 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.338); called by muse, mutect2
- HECTD1 | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KEAP1 | c.932_935delinsT p.H311_K312delinsL | In Frame Del (DEL) | VAF 71/130 reads (55%) | called by pindel, varscan2*
- LOXL1 | c.1300T>C p.F434L | Missense Mutation (SNP) | VAF 89/118 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- RBPMS | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SH2B1 | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2
- SHROOM4 | c.3074G>C p.G1025A | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.142); called by muse, mutect2
- SLC10A3 | c.377G>C p.G126A | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VCAN | c.3478C>A p.H1160N | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.021); called by muse, mutect2
- CACNA1C | c.4578G>A p.P1526= | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as rs376555924; called by muse, mutect2, varscan2
- ETS1 | c.282C>T p.D94= | Silent (SNP) | VAF 106/259 reads (41%) | called by muse, mutect2, varscan2
- FAM171A1 | c.1698C>T p.V566= | Silent (SNP) | VAF 95/260 reads (37%) | catalogued as rs746470792, COSV65320791; called by muse, mutect2, varscan2
- MYT1L | c.1293G>C p.L431= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV101219450, COSV67708093; called by muse, mutect2
- OR2L3 | c.78C>G p.L26= | Silent (SNP) | VAF 22/254 reads (9%) | called by muse, mutect2
- SCAP | c.1695T>C p.S565= | Silent (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- SEMA5A | c.2019T>C p.I673= | Silent (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- SLC23A2 | c.1785C>T p.L595= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs759841219, COSV100594964; called by muse, varscan2
- TMC5 | c.1452C>G p.L484= (on ENST00000396229 / NM_001105248.1; = p.L238= on NM_024780.5) | Silent (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- TRMT2A | c.417C>T p.L139= | Silent (SNP) | VAF 68/97 reads (70%) | called by muse, mutect2, varscan2
- ZNF648 | c.1425C>T p.P475= | Silent (SNP) | VAF 72/308 reads (23%) | called by muse, mutect2, varscan2
- GABRB3 | c.545-24G>A | Intron (SNP) | VAF 145/219 reads (66%) | called by muse, mutect2, varscan2
- GORAB | c.*146C>T | 3'UTR (SNP) | VAF 168/303 reads (55%) | catalogued as rs942688948; called by muse, mutect2, varscan2
- IQCE | c.*2del | 3'UTR (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- LINC02118 | n.45G>A | RNA (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- MAPK12 | c.1024+15C>G | Intron (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- MSRB1 | c.205-70C>G | Intron (SNP) | VAF 114/259 reads (44%) | called by muse, mutect2, varscan2
- NECAP2 | c.489+964C>T | Intron (SNP) | VAF 39/113 reads (35%) | catalogued as rs943111560; called by muse, mutect2, varscan2
- SLC38A1 | c.-567C>A | 5'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- SRP68 | c.1078-17T>G | Intron (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
